TCGA case TCGA-FJ-A871 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb38805e-2ccc-4169-ba01-34b98adf5bd0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 272 days.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,051 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T3b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 272 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 84 days; Days to treatment end: 205 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 84 days; Days to treatment end: 91 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Days to treatment start: 113 days; Days to treatment end: 189 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate + Vinblastine; Days to treatment start: 113 days; Days to treatment end: 205 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 49.7 years (18,157 days); Days to diagnosis: 106 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Subsequent primary of the pelvis (histology not recorded by GDC). Age at diagnosis: 49.7 years (18,157 days); Days to diagnosis: 106 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Day 106 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 106 days.
- Days to follow up: 272 days; Disease response: With Tumor.
- ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 177 cm; BMI: 24.9.

Exposures
- Chemical exposure type: Diesel Exhaust; Occupation type: Locomotive Engine Drivers and Related Workers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 0.15; Tobacco smoking quit year: 1982; Age at onset: 18.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FJ-A871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-FJ-A871-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FJ-A871-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FJ-A871-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Rail line worker, Maintenance equiptment operator; Occupation primary: Railway Business; Occupation primary chemical exposure: Diesel; Occupation primary industry: Railway; Tobacco smoking history indicator: 3; Tobacco smoking pack years smoked: .15; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 272 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 272 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FJ-A871-01A-11D-A34T-01): tumor purity 0.81, ploidy 1.99, whole-genome doublings 0.
